Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9TT, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9TT-01A (Primary Tumor).

ICD O-3
Lymphoma, diffuse large
B cell NOS 9680/3
Site Testis NOS C62.9
7/3/14

TESTE:

Orchiectomy specimen of 832,1 grams that measures 10 x 9 x 6 cm. Epididymis and spermatic cord segment are identified. At gross sections a well defined solid tumour of 7 x 6,5 x 3,5 cm is identified, with hemorrhagic and whitish areas, that represents 90% of the testicular volume.

TESTE (ORCHIECTOMY):

- DIFFUSE LARGE B-CELL LINFOMA WITH A HIGH PROLIFERATIVE INDEX

Histological examination shows a testicular parenchyma infiltrated by an atypical lymphoid proliferation, showing extense areas of necrosis. The tumor is constituted by layers of large atypical immunoblastic cells which replace the practical totality of the testicle.

The tumor is intensely positive for CD20, CD79a, BCL2, MUM1, with heterogeneous expression of BCL6 and is negative for CD10, CD3 and CD5. The neoplastic cells show Kappa light chain restriction. There is a very scarce intratumoral T-cell reactive lymphoid infiltration CD3 and CD5positive. The Ki67proliferation index is 100%.

Source: NCI Genomic Data Commons file e111ae7a-3a34-41a1-9689-d4b309846d7a (TCGA-GS-A9TT.7F403F75-9100-4C68-8F36-14AD78B954FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).